Surgical pathology report (de-identified scan), TCGA case TCGA-4V-A9QX, project TCGA-THYM (Thymoma), tissue source site Hospital Louis Pradel, specimen TCGA-4V-A9QX-01A (Primary Tumor).

Macroscopic examination :

Piece weighing 1208 g thymectomy fresh and measuring 19 x 17 x 8 cm. it extended by a pulmonary resection lingula measuring 8 x 5 x 2 cm . When cut , it is a yellowish white tumor lobulated showing necrotic and remodeling a small yellowish nodule.
Lymph node latero- tracheal top right measuring 1.5 cm in diameter.

Microscopic examination :

1) Thymectomy :

Many samples were taken (1A to 1D) . The tumor has an architecture lobulated . It comprises an epithelial cell proliferation primarily fusiform . These cells are grouped together in small bundles . They are arranged also small beaches. Lymphocyte contingent is also abundant enough mixed with epithelial contingent. Presence of some beaches fibrosis with remodeling inflammatory with tablecloths foamy histiocytes . No outbreak of differentiation medulla. Presence of a range of tumor necrosis . Presence of some clear spaces perivascular (1B) . The tumor is highly infiltrative and invades the lung parenchyma (1E) . The limits of resection inked in green appear microscopically healthy . Some areas appear much richer in epithelial cells with a scarcity of accompanying lymphocytes.

After immunohistochemistry , epithelial cells express cytokeratin KL1 and focally CD20. However, they are negative for CD5 and CD117 .

2) Lymph node latérotrachéal top right :

This is a little modified lymph node . No histological evidence of malignancy.

Conclusion :

Type AB thymoma in 19 cm major axis , with widely invasive invasion in the lung parenchyma stage 3 according to the classification of Masaoka . resection surgical complete.

ICD O-3

Thymoma, type AB, malignant 8582/3

Site: Thymus C379

960 4/2/14

Source: NCI Genomic Data Commons file 26791cf4-fef7-4723-97dc-08a89d747b79 (TCGA-4V-A9QX.57310D54-B73F-472F-90BC-D83DB3B7C210.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).